TARGET case TARGET-30-PADHWC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a5801af0-dc34-5bfb-ba73-73e25b43b3f9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 3.2 years (1,152 days); Year of diagnosis: 1992; Days to last follow up: 1,122 days (3.1 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PADHWC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
